MMRF case MMRF_2101 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f3664bcb-3446-4beb-a9d8-5d27326f51a9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.4 years (19,871 days); ISS stage: III; Days to last known disease status: 938 days (2.6 years); Days to last follow up: 938 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 89 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 20 days; Days to treatment end: 62 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 567 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 3.87 g/L; Immunoglobulin A 57 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 6.2 µg/mL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 28 g/L; Total Protein 10.8 g/dL; Glucose 5.56 mmol/L.
- Day 89 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 12 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 6.71 mmol/L.
- Day 173 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.893 g/L; Immunoglobulin M 0.196 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 8.91 mmol/L.
- Day 252 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.564 g/L; Immunoglobulin M 0.427 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.71 mmol/L.
- Day 364 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.224 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 6.05 mmol/L.
- Day 427 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.275 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 7.32 mmol/L.
- Day 484: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.192 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.28 mmol/L.
- Day 567 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.9 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 8.31 mmol/L.
- Day 658 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 8.91 mmol/L.
- Day 742 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 8.97 mmol/L.
- Day 848 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.34 mmol/L.
- Day 938 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 8.25 mmol/L.

Other clinical attributes
- Day -14: Weight: 60 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2101_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2101_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
